TCGA case TCGA-DX-A7EI — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Lipomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Memorial Sloan Kettering. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/2c9f737b-0d37-4931-aff5-4562a0057bae

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 78 years; Vital status: Dead; Days to death: 1,049 days (2.9 years).

Diagnoses (2)
1. Dedifferentiated liposarcoma (the primary disease): ICD-O-3 morphology code: 8858/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 78.3 years (28,610 days); Year of diagnosis: 2003; Metastasis at diagnosis: No Metastasis; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R1; Tumor focality: Multifocal.
   Pathology details: Consistent pathology review: Yes; Margin status: Involved; Necrosis present: No; Tumor depth descriptor: Deep.
   Pathology details: Measurement type: Pathologic; Tumor burden: 15.5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 1.5; Tumor length measurement: 3; Tumor width measurement: 3.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 6; Tumor width measurement: 5.5.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 4; Tumor length measurement: 6.5; Tumor width measurement: 5.
2. Recurrence of diagnosis 1 (Dedifferentiated liposarcoma), site: Retroperitoneum. Age at diagnosis: 80.6 years (29,438 days); Days to diagnosis: 828 days (2.3 years); Prior treatment: Yes; Tumor focality: Unifocal.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.

Follow-up (3 entries)
- Day 0 (initial diagnosis): Discontiguous lesion count: 3.
- Day 828 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Retroperitoneum; Days to recurrence: 828 days (2.3 years).
- Days to follow up: 1,049 days (2.9 years); Disease response: With Tumor.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-DX-A7EI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 410 mg.
  Slide TCGA-DX-A7EI-01A-01-TSA: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-DX-A7EI-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-DX-A7EI-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology: Margin status: Positive; Tumor total necrosis: 0% (no necrosis or no mention of necrosis); Disease multifocal indicator: Yes; Discontinuous lesions count: 3; Locoregional recurrence indicator: Yes; Metastatic disease confirmed: No; Well diff liposarc prior diagnosis indicator: No.
- Primary pathology, Tumor sizes, Tumor size 1: Lesion pathologic length: 6.0; Lesion pathologic depth: 4.0.
- Primary pathology, Tumor sizes, Tumor size 2: Lesion pathologic length: 3.0; Lesion pathologic width: 3.0.
- Primary pathology, Tumor sizes, Tumor size 3: Lesion pathologic width: 5.0; Lesion pathologic depth: 4.0.
- Drug treatment: Treatment on clinical trial: No; Days from index date to pharmaceutical treatment started: 990; Days from index date to pharmaceutical treatment ended: 991; Pharmaceutical therapy drug name: Doxil; Pharmaceutical treatment ongoing indicator: No.
- Drug treatment, Therapy types: Pharmaceutical therapy type: Chemotherapy.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,049 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,049 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 828 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-DX-A7EI-01A-11D-A33D-01): tumor purity 0.89, ploidy 3.14, whole-genome doublings 1.
